Somatic mutation profile of tumor specimen MP2PRT-PATBWC-TMP1-A (aliquot MP2PRT-PATBWC-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATBWC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.6 years (2,785 days).
Specimen MP2PRT-PATBWC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36764517-c41f-4dba-9b71-bc6df828a0b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATBWC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATBWC-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3e3ca2a-9231-4d42-92e6-093c40f591b1

The open-access MAF lists 75 somatic variants for this specimen: 51 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 21, Nonsense Mutation 7, 3'Flank 1, In Frame Del 1, Frame Shift Ins 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP250 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 27/243 reads (11%) | catalogued as rs1341298773, COSV61170127; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMZ2 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as rs201005237; called by muse, mutect2, varscan2
- CTNNA2 | c.1259T>A p.V420D | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as rs1263495673, COSV100560060, COSV58135013, COSV58149761; called by muse, mutect2, varscan2
- FAM50B | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 91/432 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs1484366992, COSV66654735; called by muse, mutect2, varscan2
- FREM1 | c.2501C>T p.S834L | Missense Mutation (SNP) | VAF 41/371 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs773954800; called by muse, mutect2
- GFI1B | c.755T>A p.F252Y | Missense Mutation (SNP) | VAF 231/499 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs944694471; called by muse, mutect2, varscan2
- GRM8 | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 32/422 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV100282798; called by muse, mutect2
- GSX2 | c.685C>G p.R229G | Missense Mutation (SNP) | VAF 12/360 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58842837; called by muse, mutect2
- HS3ST4 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 67/790 reads (8%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.027); catalogued as rs1227867289; called by muse, mutect2
- MOB3C | c.295C>G p.R99G | Missense Mutation (SNP) | VAF 18/557 reads (3%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.559); catalogued as COSV99596296; called by muse, mutect2
- MOB3C | c.294C>G p.Y98* | Nonsense Mutation (SNP) | VAF 18/563 reads (3%) | catalogued as COSV99596480; called by muse, mutect2
- NAV3 | c.2951C>T p.S984L | Missense Mutation (SNP) | VAF 34/281 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs1005877698, COSV57058762; called by muse, mutect2, varscan2
- PDZD4 | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 48/574 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs369369481; called by muse, mutect2
- PTPRS | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 136/339 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as rs147257283; called by muse, mutect2, varscan2
- RSPH6A | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 112/575 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.767); catalogued as rs1158801086, COSV55575485; called by muse, mutect2, varscan2
- SRA1 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 39/416 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs369799757; called by muse, mutect2
- USH2A | c.3261C>G p.Y1087* | Nonsense Mutation (SNP) | VAF 111/271 reads (41%) | catalogued as COSV56430935; called by muse, mutect2, varscan2
- YME1L1 | c.875G>A p.R292Q (on ENST00000326799 / NM_139312.3; = p.R235Q on NM_014263.4) | Missense Mutation (SNP) | VAF 61/279 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.848); catalogued as rs1172430825; called by muse, mutect2, varscan2
- ADGRB2 | c.4562G>A p.S1521N (on ENST00000373658 / NM_001364857.2; = p.S1520N on NM_001294335.2) | Missense Mutation (SNP) | VAF 42/496 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- ANK1 | c.323C>A p.S108* | Nonsense Mutation (SNP) | VAF 32/293 reads (11%) | called by muse, mutect2, varscan2
- BRWD3 | c.4012C>T p.Q1338* | Nonsense Mutation (SNP) | VAF 26/218 reads (12%) | called by muse, mutect2, varscan2
- FAS | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 20/221 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.198); called by muse, mutect2
- GPATCH8 | c.4137C>G p.I1379M | Missense Mutation (SNP) | VAF 43/442 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2
- GRIA1 | c.2372G>A p.G791E | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.035); called by muse, mutect2
- HSPA6 | c.732G>A p.M244I | Missense Mutation (SNP) | VAF 52/360 reads (14%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV3-20 | c.348_353del p.A116_R117del | In Frame Del (DEL) | VAF 35/99 reads (35%) | called by pindel*, varscan2
- IGHV4-39 | c.370_371insGGCCTTG p.A124Gfs*? | Frame Shift Ins (INS) | VAF 60/94 reads (64%) | called by pindel, varscan2
- IGLJ3 | c.108_115delinsCCCAGTGG p.Q37_W39delinsPVG | Missense Mutation (ONP) | VAF 135/601 reads (22%) | called by pindel, varscan2*
- IQSEC2 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 57/689 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.966); called by muse, mutect2
- KCNH7 | c.3029C>T p.S1010F | Missense Mutation (SNP) | VAF 21/360 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- MAGEC1 | c.2510C>G p.S837C | Missense Mutation (SNP) | VAF 30/515 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- MELK | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 17/276 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MOCS3 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 21/346 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.221); called by muse, mutect2
- NBPF11 | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 31/355 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- NOD1 | c.1678C>A p.P560T | Missense Mutation (SNP) | VAF 30/444 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.027); called by muse, mutect2
- PBX2 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 36/487 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- PCDH7 | c.2155G>C p.D719H | Missense Mutation (SNP) | VAF 44/365 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PEX2 | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 36/323 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- PLXNC1 | c.3046C>T p.L1016F | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRQ | c.2404G>C p.D802H (on ENST00000616559; = p.D760H on NM_001145026.2) | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2
- RNF5 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 27/368 reads (7%) | called by muse, mutect2
- RNF5 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 48/538 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.031); called by muse, mutect2
- SLF1 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 28/257 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TOGARAM2 | c.182A>G p.E61G | Missense Mutation (SNP) | VAF 91/364 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TROAP | c.1268G>A p.R423K | Missense Mutation (SNP) | VAF 31/412 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- TROAP | c.1963G>C p.E655Q | Missense Mutation (SNP) | VAF 47/568 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.269); called by muse, mutect2
- TSG101 | c.1047G>C p.L349F | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TSHB | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.079); called by muse, mutect2
- UHRF2 | c.2113C>G p.Q705E | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- USP17L4 | c.406C>A p.L136I | Missense Mutation (SNP) | VAF 74/330 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, varscan2
- WDR62 | c.3299C>G p.S1100* | Nonsense Mutation (SNP) | VAF 12/366 reads (3%) | called by muse, mutect2
- ARHGAP1 | c.954C>G p.L318= | Silent (SNP) | VAF 36/354 reads (10%) | catalogued as COSV100357751; called by muse, varscan2
- CACNA2D3 | c.126G>A p.V42= | Silent (SNP) | VAF 31/281 reads (11%) | called by muse, mutect2, varscan2
- DPM2 | c.33C>G p.L11= | Silent (SNP) | VAF 37/366 reads (10%) | called by muse, mutect2, varscan2
- GPR39 | c.300C>G p.T100= | Silent (SNP) | VAF 35/450 reads (8%) | called by muse, mutect2
- GPX7 | c.27G>A p.A9= | Silent (SNP) | VAF 36/401 reads (9%) | catalogued as rs1443708709; called by muse, mutect2
- HPRT1 | c.366C>T p.L122= | Silent (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- KANK4 | c.900G>A p.L300= | Silent (SNP) | VAF 48/362 reads (13%) | called by muse, mutect2, varscan2
- KCNMA1 | c.1647C>T p.I549= | Silent (SNP) | VAF 49/326 reads (15%) | called by muse, mutect2, varscan2
- KRTAP16-1 | c.54C>G p.L18= | Silent (SNP) | VAF 40/532 reads (8%) | called by muse, mutect2
- LZTS1 | c.1716C>T p.S572= | Silent (SNP) | VAF 146/396 reads (37%) | catalogued as rs1168753207, COSV56118467; called by muse, mutect2, varscan2
- NUP214 | c.456G>A p.V152= | Silent (SNP) | VAF 25/347 reads (7%) | called by muse, mutect2
- OR2G2 | c.109C>T p.L37= | Silent (SNP) | VAF 41/339 reads (12%) | catalogued as COSV60740641, COSV60741104; called by muse, mutect2, varscan2
- PPP4C | c.57C>T p.L19= | Silent (SNP) | VAF 60/604 reads (10%) | catalogued as rs573008472; called by muse, mutect2
- RELN | c.5418C>T p.D1806= | Silent (SNP) | VAF 71/336 reads (21%) | catalogued as rs746613525; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- RIMBP3 | c.1164G>A p.A388= | Silent (SNP) | VAF 40/424 reads (9%) | called by muse, varscan2
- TEX13C | c.429C>T p.C143= | Silent (SNP) | VAF 81/392 reads (21%) | catalogued as rs1215981332; called by muse, mutect2, varscan2
- TMEM154 | c.39G>C p.V13= | Silent (SNP) | VAF 59/455 reads (13%) | called by muse, mutect2, varscan2
- TMEM74 | c.504G>A p.T168= | Silent (SNP) | VAF 61/352 reads (17%) | catalogued as rs770087708, COSV52463814; called by muse, mutect2, varscan2
- TNR | c.1014C>T p.S338= | Silent (SNP) | VAF 37/334 reads (11%) | catalogued as rs779406233, COSV54891052; called by muse, mutect2, varscan2
- TSG101 | c.1119G>C p.L373= | Silent (SNP) | VAF 24/314 reads (8%) | called by muse, mutect2
- VWA1 | c.223C>T p.L75= | Silent (SNP) | VAF 34/532 reads (6%) | called by muse, mutect2
- ARMCX4 | c.1039-3418C>G | Intron (SNP) | VAF 120/311 reads (39%) | called by muse, mutect2, varscan2
- CSF2RA | c.*77G>A | 3'UTR (SNP) | VAF 51/385 reads (13%) | called by muse, mutect2, varscan2
- PVRIG | chr7:100223905 del T | 3'Flank (DEL) | VAF 38/202 reads (19%) | called by pindel*, varscan2
